Somatic mutation profile of tumor specimen TARGET-10-PATSIL-09A (aliquot TARGET-10-PATSIL-09A-01D) from TARGET case TARGET-10-PATSIL, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.6 years (5,700 days).
Specimen TARGET-10-PATSIL-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54aebb8a-39da-4e3d-b54a-b2db79fcbd25.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATSIL-10A (Blood Derived Normal), aliquot TARGET-10-PATSIL-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b0fec32a-ee6a-4cad-a50b-4a9ac408c7a6

The open-access MAF lists 16 somatic variants for this specimen: 6 protein-altering or splice-affecting, 5 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 5, Missense Mutation 3, Intron 3, Nonsense Mutation 1, 3'UTR 1, In Frame Ins 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COPA | c.1685G>T p.R562L | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54101815, COSV54111187; called by muse, mutect2, varscan2
- KCNC2 | c.1434G>T p.M478I | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as COSV54377039; called by muse, mutect2, varscan2
- SYT4 | c.933_934insAATCC p.R312Nfs*20 | Frame Shift Ins (INS) | VAF 16/49 reads (33%) | catalogued as COSV54905162; called by mutect2, pindel, varscan2
- TTN | c.39955C>T p.R13319* (on ENST00000591111; = p.R5895* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 16/49 reads (33%) | catalogued as COSV59979106; called by muse, mutect2, varscan2
- HERC2 | c.13645C>T p.P4549S | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- HIP1R | c.1399_1400insGGA p.R466dup | In Frame Ins (INS) | VAF 22/66 reads (33%) | called by mutect2, pindel, varscan2
- BAIAP2L1 | c.1302C>T p.I434= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV50054826; called by muse, mutect2, varscan2
- CLCN4 | c.99C>T p.I33= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as rs758152688, COSV104433006; called by muse, varscan2
- IL22RA1 | c.843C>T p.H281= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as rs138064122; called by muse, mutect2, varscan2
- TMCO6 | c.1074T>A p.P358= | Silent (SNP) | VAF 20/47 reads (43%) | called by muse, mutect2, varscan2
- TSHZ3 | c.1749C>A p.V583= | Silent (SNP) | VAF 24/69 reads (35%) | called by muse, mutect2, varscan2
- AC078899.1 | n.1124G>A | RNA (SNP) | VAF 8/81 reads (10%) | catalogued as rs539956470; called by muse, mutect2
- BABAM2 | c.1088+11791T>C | Intron (SNP) | VAF 6/17 reads (35%) | called by muse, mutect2
- NIPBL | c.8049+41C>T | Intron (SNP) | VAF 7/17 reads (41%) | catalogued as rs200976286, COSV56944964; called by muse, mutect2
- RPLP0 | c.54+500G>A | Intron (SNP) | VAF 5/17 reads (29%) | catalogued as rs1468864379; called by mutect2, varscan2
- SEMA3B | c.*134G>A | 3'UTR (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2, varscan2
